Somatic mutation profile of tumor specimen TCGA-5R-AA1C-01A (aliquot TCGA-5R-AA1C-01A-11D-A40R-10) from TCGA case TCGA-5R-AA1C, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 57.7 years (21,073 days).
Specimen TCGA-5R-AA1C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51e4a7bb-544f-48b9-9c54-023b140937ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5R-AA1C-10A (Blood Derived Normal), aliquot TCGA-5R-AA1C-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/509d06bd-210a-4fb5-a161-ee6fe46e65a4

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 23, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Translation Start Site 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 91/166 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.1803T>G p.D601E | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV101201286; called by muse, mutect2, varscan2
- ACKR1 | c.979T>A p.S327T | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100929669; called by muse, mutect2, varscan2
- ADAM12 | c.1423-1G>T p.X475_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100901564; called by muse, mutect2, varscan2
- ADAMTS20 | c.2369A>G p.Q790R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs1476022407, COSV101166400; called by muse, mutect2, varscan2
- AFF2 | c.2264C>T p.T755I | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1557287335, COSV99666387; called by muse, mutect2, varscan2
- AGO2 | c.1430T>A p.I477N | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99596454; called by muse, mutect2, varscan2
- ALK | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1178904580, COSV101202740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1617G>A p.M539I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV99231604; called by muse, mutect2, varscan2
- AZIN1 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 20/183 reads (11%) | catalogued as COSV100457831; called by muse, mutect2, varscan2
- BACH1 | c.1760C>A p.S587* | Nonsense Mutation (SNP) | VAF 39/74 reads (53%) | catalogued as COSV99728729; called by muse, mutect2, varscan2
- CFAP61 | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as COSV99846703; called by muse, mutect2
- COBLL1 | c.1897A>G p.M633V (on ENST00000392717; = p.M595V on NM_014900.5) | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs145390469; called by muse, mutect2, varscan2
- COL4A3 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101170542; called by muse, mutect2, varscan2
- CROCC | c.5867A>T p.Q1956L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.033); catalogued as COSV100977651; called by muse, mutect2, varscan2
- CXCL13 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99724309; called by muse, mutect2, varscan2
- DNAH7 | c.9534G>T p.L3178F | Missense Mutation (SNP) | VAF 129/475 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417662; called by muse, mutect2, varscan2
- DNAJC13 | c.4480A>G p.I1494V | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV99608162; called by muse, mutect2, varscan2
- DOCK2 | c.2986C>T p.Q996* | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | catalogued as COSV99915578; called by muse, mutect2, varscan2
- EMILIN1 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as rs760821968, COSV99565824; called by muse, mutect2, varscan2
- GABRG1 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54959528; called by muse, mutect2, varscan2
- GFM2 | c.1744T>G p.L582V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as COSV99714702; called by muse, mutect2, varscan2
- GOLGA4 | c.6577-1G>A p.X2193_splice | Splice Site (SNP) | VAF 28/122 reads (23%) | catalogued as COSV100729183; called by muse, mutect2, varscan2
- GOT1 | c.247T>G p.C83G | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100981830; called by muse, mutect2, varscan2
- HCRTR2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904654; called by muse, mutect2, varscan2
- HMCES | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 99/183 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101077399; called by muse, mutect2, varscan2
- HMGCLL1 | c.1078A>T p.N360Y | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV99233256; called by muse, mutect2, varscan2
- HRG | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs759656714, COSV99215083; called by muse, mutect2
- HTR5A | c.975G>C p.W325C | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV99840001; called by muse, mutect2, varscan2
- INTS5 | c.2287T>C p.F763L | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100399833; called by muse, mutect2, varscan2
- ITGAE | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV99561567; called by muse, mutect2
- JAK2 | c.382A>T p.S128C | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV101079633; called by muse, mutect2, varscan2
- KCNB1 | c.1694T>C p.I565T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.041); catalogued as COSV100870597; called by muse, mutect2, varscan2
- KCNN3 | c.346T>A p.S116T | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); catalogued as COSV99679292; called by muse, mutect2
- KRTAP5-1 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs1448318120, COSV101192945; called by muse, mutect2, varscan2
- LILRA6 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99558043; called by muse, mutect2, varscan2
- LINGO1 | c.684T>A p.N228K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100796517; called by muse, mutect2, varscan2
- MAP2K4 | c.783_784del p.D263Cfs*4 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as COSV62256622; called by mutect2, pindel, varscan2
- MAP3K11 | c.2442C>A p.D814E | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100442383; called by muse, mutect2, varscan2
- MTHFD1 | c.2542A>C p.K848Q | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.305); catalogued as COSV99387402; called by muse, mutect2, varscan2
- NCDN | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV100622187; called by muse, mutect2, varscan2
- NTPCR | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 102/159 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV100786755; called by muse, mutect2, varscan2
- OBSCN | c.10282G>C p.G3428R | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99484478; called by muse, mutect2, varscan2
- OLFM4 | c.1330C>A p.R444S | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99524579; called by muse, mutect2, varscan2
- PDE6B | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs1286551313, COSV99728426; called by muse, mutect2, varscan2
- PDZRN3 | c.1765A>C p.N589H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99732179; called by muse, mutect2, varscan2
- PRG4 | c.3839A>G p.K1280R | Missense Mutation (SNP) | VAF 123/191 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV100798332; called by muse, mutect2, varscan2
- PRPF8 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100517945; called by muse, mutect2, varscan2
- PTPRS | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99512521; called by muse, mutect2, varscan2
- RCAN3 | c.377T>C p.M126T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537312929, COSV100980362; called by muse, mutect2, varscan2
- RCN2 | c.150T>A p.D50E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs932630417, COSV100312877; called by muse, mutect2, varscan2
- SACM1L | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV101203805; called by muse, mutect2, varscan2
- SBNO2 | c.3185G>A p.G1062D | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs1328557720, COSV100685042; called by muse, mutect2, varscan2
- SH3BP4 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100749333; called by muse, mutect2, varscan2
- SHC1 | c.750G>T p.Q250H (on ENST00000368445 / NM_183001.5; = p.Q140H on NM_003029.5) | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV63534941; called by muse, mutect2, varscan2
- SKIV2L | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV100952867; called by muse, mutect2, varscan2
- STK32B | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.085); catalogued as COSV99285898, COSV99287463; called by muse, mutect2, varscan2
- SYCP3 | c.509A>T p.Q170L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57148772, COSV99901784; called by muse, mutect2, varscan2
- SYNE1 | c.448A>C p.S150R (on ENST00000367255 / NM_182961.4; = p.S157R on NM_033071.3) | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV99579453; called by muse, mutect2, varscan2
- SYS1 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV54781528; called by muse, mutect2, varscan2
- TAOK1 | c.2147A>T p.K716M | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99914783; called by muse, mutect2, varscan2
- TEAD3 | c.1151A>G p.K384R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.62); catalogued as COSV100132668; called by muse, mutect2, varscan2
- TMEM67 | c.313-2A>G p.X105_splice | Splice Site (SNP) | VAF 63/109 reads (58%) | catalogued as COSV100019923; called by muse, mutect2, varscan2
- TOX4 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99398629; called by muse, mutect2, varscan2
- TSPYL4 | c.182del p.G61Vfs*71 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV60310254; called by mutect2, varscan2
- TTC19 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 83/774 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.227); catalogued as COSV99890424; called by muse, mutect2, varscan2
- UPF2 | c.1730A>C p.N577T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.289); catalogued as COSV100707463; called by muse, mutect2, varscan2
- VIRMA | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 39/134 reads (29%) | catalogued as COSV99889511; called by muse, mutect2, varscan2
- ZMYND11 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100556937; called by muse, mutect2, varscan2
- ZNF3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as COSV99447406; called by muse, mutect2, varscan2
- ATG5 | c.26_28del p.R9_D10delinsH | In Frame Del (DEL) | VAF 27/38 reads (71%) | called by mutect2, pindel, varscan2
- HMCN1 | c.5276dup p.G1760Rfs*17 | Frame Shift Ins (INS) | VAF 98/262 reads (37%) | called by mutect2, pindel, varscan2
- MRC1 | c.4210G>T p.G1404C | Missense Mutation (SNP) | VAF 179/488 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SPATA31A3 | c.429A>T p.E143D | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- WASHC2C | c.3814G>A p.D1272N (on ENST00000336378; = p.D1251N on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 193/654 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ADGRB3 | c.3987T>C p.N1329= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV99486930; called by muse, mutect2, varscan2
- CACNA1A | c.136A>C p.R46= | Silent (SNP) | VAF 334/864 reads (39%) | catalogued as COSV100803259; called by muse, mutect2, varscan2
- CEACAM5 | c.1050G>A p.Q350= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV99704169; called by muse, mutect2, varscan2
- CNOT4 | c.558T>A p.L186= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100212258; called by muse, mutect2, varscan2
- CORO2B | c.1203T>C p.Y401= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV99963752; called by muse, mutect2, varscan2
- DMXL2 | c.669A>G p.Q223= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as rs758262028, COSV99198632; called by muse, mutect2, varscan2
- FLNC | c.7039C>T p.L2347= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs769053602, COSV100368769; called by muse, mutect2, varscan2
- FUT6 | c.57G>T p.T19= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV99744985; called by muse, mutect2, varscan2
- GNAL | c.264G>C p.A88= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs1381154666, COSV100476974; called by muse, mutect2, varscan2
- H2AC12 | c.57T>C p.S19= | Silent (SNP) | VAF 55/255 reads (22%) | catalogued as COSV100804766, COSV63617490; called by muse, mutect2, varscan2
- HECTD1 | c.4776T>C p.G1592= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV101237523; called by muse, mutect2, varscan2
- HEXB | c.69G>A p.L23= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as COSV99784485; called by muse, mutect2, varscan2
- IFNAR2 | c.1134C>T p.P378= | Silent (SNP) | VAF 40/62 reads (65%) | catalogued as COSV99270169; called by muse, mutect2, varscan2
- KCNJ2 | c.882C>A p.I294= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV54664076, COSV99696545; called by muse, mutect2, varscan2
- MED27 | c.282G>T p.L94= | Silent (SNP) | VAF 55/91 reads (60%) | catalogued as COSV99406894; called by muse, mutect2, varscan2
- PAX9 | c.666G>A p.V222= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as COSV100825899; called by muse, mutect2
- SFI1 | c.2799A>G p.K933= (on ENST00000400288 / NM_001007467.3; = p.K902= on NM_014775.4) | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV99837409; called by muse, mutect2, varscan2
- SLC66A3 | c.537C>T p.I179= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV54468234, COSV99706427; called by muse, mutect2, varscan2
- SPEM1 | c.450C>A p.V150= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100081289; called by muse, mutect2, varscan2
- TJAP1 | c.1659C>G p.G553= (on ENST00000372445 / NM_001146016.1; = p.G543= on NM_080604.3) | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99447554; called by muse, mutect2, varscan2
- UNC79 | c.6799C>T p.L2267= (on ENST00000393151 / NM_001346218.2; = p.L2090= on NM_020818.5) | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99829895; called by muse, mutect2, varscan2
- XKR4 | c.540T>A p.A180= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs913159068, COSV100534101; called by muse, mutect2, varscan2
- ZNF423 | c.2097C>T p.H699= (on ENST00000563137 / NM_001379286.1; = p.H691= on NM_015069.4) | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99283869; called by muse, mutect2, varscan2
- NAP1L3 | c.-1G>T | 5'UTR (SNP) | VAF 69/164 reads (42%) | catalogued as COSV100220528, COSV100220700; called by muse, mutect2, varscan2
- SSPOP | n.12839C>A | RNA (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100948076; called by muse, mutect2
